Surgical pathology report (de-identified scan), TCGA case TCGA-19-1788, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1788-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS

A. TEMPORAL TIP, B. ENHANCING LESION, C. PERMANENT CORE, D. HIPPOCAMPUS, E. ENHANCING LESION AND F. POSTERIOR TEMPORAL, BIOPSY AND REMOVAL:
--GLIOBLASTOMA MULTIFORME (WHO GRADE IV), SEE NOTE.

Note: Much of the lesion has the appearance of a grade II or grade III astrocytoma and some areas show morphologic features suggestive of oligodendroglial differentiation, however there is a focus of tumor on part E with necrosis, vascular proliferation and morphologic features consistent with glioblastoma multiforme.

Fluorescence in situ hybridization for chromosome 1p and 19q deletions performed at the [REDACTED] shows both chromosomes intact within the segments examined.

The slides from this specimen were sent to [REDACTED] of the [REDACTED] for review. A copy of his report is retained in the Department of Anatomic Pathology files.

Electronically Signed Out By

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consult Diagnosis

A: Touch Imprint: Glioma with oligodendroglial differentiation. B: Microscopic: Astrocytoma, probable anaplastic.

Clinical History:

right low grade glioma

Specimens Submitted As:

A: TEMPORAL TIP
B: ENHANCING LESION
C: PERMANENT CORE
D: HIPPOCAMPUS
E: ENHANCING LESION
F: POSTERIOR TEMPORAL

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name, hospital number, and "temporal tip", is an irregular section of the brain, 4 x 3.5 x 1.4 cm. Cerebral cortex and white matter are identified. The white matter is soft. Touch imprint is performed. The specimen is submitted entirely in seven cassettes.

B: Received fresh for intraoperative consultation, labelled with the patient's name, hospital number, and "enhancing lesion", is an irregular fragment of white-tan, 1.5 x 0.5 x 0.4 cm. A frozen section is performed. Submitted entirely in two cassettes.

C: Received in formalin labeled with the patient's name and number, and "A", are multiple irregular, opaque white to pink-tan, soft, cerebriform tissue fragments measuring in aggregate 6.5 x 4.8 x 2.5 cm. Submitted entirely in 23 cassettes.

[page 2 of 2]
D:Received in formalin labeled with the patient's name and number, and "B", are two irregular fragments of opaque white to pink tan, soft, cerebriform tissue measuring in aggregate 1.0 x 0.4 x 0.2 cm. Submitted in toto in one cassette.

E:Received in formalin labeled with the patient's name and number, and ", are multiple irregular, opaque white to pink-tan, soft, tan tissue fragments measuring in aggregate 1.9 x 1.8 x 0.6 cm. Submitted in toto in two cassettes.

F:Received in formalin labeled with the patient's name and number, and "D", are multiple fragments of pink-tan, soft, cerebriform tissue measuring in aggregate 6.7 x 3.2 x 2.2 cm. Submitted entirely in 13 cassettes.

Summary of Cassettes:

B 1FS
2 remainder of specimen

TCGA-19-1788

Source: NCI Genomic Data Commons file 16e52562-b010-4240-bc29-1e19aeadcf63 (TCGA-19-1788.1444B194-81D0-40EC-90CE-AF7E5EDFC645.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).